Surgical pathology report (de-identified scan), TCGA case TCGA-FE-A235, project TCGA-THCA (Thyroid Carcinoma), tissue source site Ohio State University, specimen TCGA-FE-A235-01A (Primary Tumor).

[page 1 of 3]
Print this Page

Specimen Description

Thyroid, REG

Surgical Pathology Report

Patient Name: [REDACTED]

Accession #: [REDACTED]

Med. Rec #: [REDACTED]

Submitting Physician: [REDACTED]

Clinical History

Thyroid cancer.

ICD-0-3

carcinoma, papillary, thyroid 8220/3

Site: thyroid, NOS C73.9 lw 4/8/11

*****Final Pathologic Diagnosis*****

A. Thyroid mass:

- Papillary thyroid carcinoma. See synoptic report and comment.

B. Thyroid:

- Papillary thyroid carcinoma, multifocal, with the largest lesion measuring 3.1 cm in greatest dimension. See synoptic report and comment.
- Lymph nodes (x4): three positive for metastases.
- Tissue from involuting thymus.
- Tissue from parathyroid (x1).

Electronically Signed By

*****Synoptic Report*****

SYNOPTIC REPORT FOR THYROID CANCER:

Specimen type: thyroid gland

Tumor location: multifocal, with the largest focus present in the isthmus

Tumor size: varies from less than one millimeter to 3.0 x 2.0 x 1.4 cm

Histologic type: papillary thyroid carcinoma, usual type

Lymphatic/vascular invasion: yes (intrathyroid and in the vascular sinuses of one of the 3 lymph nodes)

Capsular invasion: no

Margins: tumor is noted at the apparent (inked) surgical margin of resection of the thyroid focally

Multifocal: yes

Lymph nodes:

Total number examined: 4

Sites: associated with the perithyroidal connective tissue (lymph nodes are 0.3 cm in greatest dimension)

Number positive: 3. All the metastatic foci are microscopic, with the

[page 2 of 3]
Results

SURG PATH

Result Status
Information

Provider Status
Ordered

Observation Date and
Time /

Entry Date

Result Thyroid, REG
Narrative

Surgical Pathology Report

Clinical History
Thyroid cancer.

*****Final Pathologic Diagnosis*****

- A. Thyroid mass:
- Papillary thyroid carcinoma. See synoptic report and comment.
- B. Thyroid:
- Papillary thyroid carcinoma, multifocal, with the largest lesion measuring 3.1 cm in greatest dimension. See synoptic report and comment.
- Lymph nodes (x4): three positive for metastases.
- Tissue from involuting thymus.
- Tissue from parathyroid (x1).

Electronically Signed By

*****Synoptic Report*****

SYNOPTIC REPORT FOR THYROID CANCER:
Specimen type: thyroid gland
Tumor location: multifocal, with the largest focus present in the isthmus
Tumor size: varies from less than one millimeter to 3.0 x 2.0 x 1.4 cm
Histologic type: papillary thyroid carcinoma, usual type
Lymphatic/vascular invasion: yes (intrathyroid and in the vascular sinuses of one of the 3 lymph nodes)
Capsular invasion: no
Margins: tumor is noted at the apparent (inked) surgical margin of resection of the thyroid focally
Multifocal: yes
Lymph nodes:

[page 3 of 3]
[REDACTED]

Total number examined: 4

Sites: associated with the perithyroidal connective tissue (lymph nodes are 0.3 cm in greatest dimension)

Number positive: 3. All the metastatic foci are microscopic, with the largest measuring 1 mm in greatest dimension

Number negative: 1

Extranodal extension: no

Additional pathologic findings: chronic lymphocytic thyroiditis

TNM: pT2, pN1, pMX

Comments: The 4 lymph nodes were identified microscopically (slides 1, 3, 4, and 7) in the immediate perithyroidal soft tissue. The largest lymph node measured 3 mm in greatest dimension. Also identified microscopically was tissue from a parathyroid and tissue from an involuting thymus. This case was presented at the intradepartmental.

The final diagnoses rendered in this case also reflect the consensus opinion of those in attendance.

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists and the Association of Directors of Anatomic and Surgical Pathology for the reporting of cancer specimens

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

AF1. Thyroid mass: (FROZEN SECTION PERFORMED)

- Findings consistent with papillary carcinoma of thyroid, [REDACTED]
[REDACTED] agrees.

Examining pathologist: [REDACTED]

SPECIMEN(S) RECEIVED:

A: Thyroid, REG

B: Thyroid, REG

GROSS DESCRIPTION:

The specimens are received in two properly labeled containers with the patient's name and accession number.

A. The specimen is designated "thyroid mass" and consists of 1.2 x 0.8 x 0.7 cm, red-brown, soft, pliable portion of tissue. Frozen section cassette AF1 is resubmitted as received. TE 1

B. The specimen is designated "thyroid" and consists of a thyroid gland that measures 6.5 x 3.3 x 1.5 cm. The specimen has a slightly shaggy but apparently intact capsule, with no parathyroid or lymph nodes identified on the outer surface grossly. The outer surface is inked black prior to sectioning. Centrally located within the specimen is a 3.1 x 2.0 x 1.4 cm, tan-pink, fleshy mass that abuts the capsular surface and is located 2.8 cm from one apex of the specimen and 3.0 cm from the opposing apex. The mass is well circumscribed. The remaining thyroid parenchyma is deep red and pliable. RS 8

Summary of Cassettes: B1-7, entire mass; B8, apparently uninvolved thyroid parenchyma

Gross description by: [REDACTED]

This result is currently not released to

Source: NCI Genomic Data Commons file 8270d754-bdc1-4a87-8dd0-22b2514f3694 (TCGA-FE-A235.E8842900-CA70-4C4E-96CB-07E2040BBC72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).